FM case AD3000 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mucoepidermoid Neoplasms; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/bd174abd-fc5d-48ca-9e17-725f68dd12aa

Male, 65.3 years: Mucoepidermoid carcinoma (ICD-O-3 8430/3) of the major salivary gland; specimen biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
